Gene-level copy-number profile of tumor specimen ALCH-B2MS-TTP1-A from ALCHEMIST case ALCH-B2MS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 61.3 years (22,392 days).
Specimen ALCH-B2MS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 063baba4-2c6d-43b2-98a6-697a61688943.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2MS-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/67fc0a40-9deb-4f85-8eca-af5f7bb31978

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 5,274; copy number 2: 50,393; copy number 3: 3,195; copy number 4: 17; copy number 5: 1; copy number 9: 3.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,693,124–7,700,970, 3 genes (within-gene range 0–2): AL359881.3, AL359881.2, AL359881.1.
- chr2:232,368,576–232,387,457, 4 genes: AC068134.3, ALPP, AC068134.1, ECEL1P2.
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr15:25,194,921–25,215,622, 12 genes (within-gene range 0–2): SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25.
- chr19:19,512,418–19,537,581, 4 genes: TSSK6, NDUFA13, AC011448.1, YJEFN3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:181,306,502–181,324,685, 1 gene, copy number 9: AC138035.1.
- chr19:1,852,399–1,863,579, 2 genes, copy number 9 (within-gene range 2–9): KLF16, AC012615.4.
- chr21:45,234,308–45,264,548, 1 gene, copy number 5 (within-gene range 2–5): LINC00334.

Autosomal genes at a single copy (total copy number 1): 2,779. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
